Somatic mutation profile of tumor specimen 0DA2XG from CCDI case PBBJLB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,646 days).
Specimen 0DA2XG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84919ebf-cb85-4b87-b1fe-0c1149ccaa25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA2XH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/303ec2f7-78d0-448b-9dd2-5792ca6e22ee

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Splice Region 2, In Frame Del 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 137/565 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 239/305 reads (78%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BICRA | c.4085C>T p.T1362M | Missense Mutation (SNP) | VAF 40/520 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs560545496; called by muse, mutect2
- FZD2 | c.1680C>G p.H560Q | Missense Mutation (SNP) | VAF 121/418 reads (29%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as rs1038724972; called by muse, mutect2, varscan2
- LEFTY1 | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 315/1120 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1189662048; called by muse, mutect2, varscan2
- LRP2BP | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1335684247; called by muse, mutect2
- PRDM9 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs765775694, COSV99690137; called by muse, mutect2, varscan2
- SLA | c.134G>A p.R45Q (on ENST00000338087 / NM_001045556.3; = p.R85Q on NM_006748.4) | Missense Mutation (SNP) | VAF 224/562 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs572664813, COSV55082496; called by muse, mutect2, varscan2
- USP11 | c.2564C>G p.S855C (on ENST00000218348; = p.S812C on NM_001371072.1) | Missense Mutation (SNP) | VAF 143/176 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99510790; called by muse, mutect2, varscan2
- ZFAND2B | c.528-5C>T | Splice Region (SNP) | VAF 307/670 reads (46%) | catalogued as rs768574846, COSV54699784; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6446A>G p.N2149S | Missense Mutation (SNP) | VAF 180/434 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CDHR1 | c.2340C>A p.N780K | Missense Mutation (SNP) | VAF 60/802 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.36); called by muse, mutect2
- CPLANE1 | c.9476A>G p.D3159G | Missense Mutation (SNP) | VAF 65/536 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MYO1G | c.1687C>A p.Q563K | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR9A2 | c.87A>G p.I29M | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2
- PGLYRP2 | c.894C>G p.H298Q | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PIK3CA | c.306_314del p.E103_V105del | In Frame Del (DEL) | VAF 100/479 reads (21%) | called by mutect2, pindel, varscan2
- SERPINB5 | c.169-3C>G | Splice Region (SNP) | VAF 48/255 reads (19%) | called by muse, mutect2, varscan2
- DNAJC22 | c.528G>A p.E176= | Silent (SNP) | VAF 230/693 reads (33%) | catalogued as rs371991713; called by muse, mutect2, varscan2
- H1-3 | c.336G>T p.A112= | Silent (SNP) | VAF 201/524 reads (38%) | catalogued as rs1460919710; called by muse, mutect2, varscan2
- KLF18 | c.1452C>T p.A484= | Silent (SNP) | VAF 207/307 reads (67%) | called by muse, mutect2, varscan2
- APP | c.-100G>A | 5'UTR (SNP) | VAF 25/44 reads (57%) | catalogued as rs915486295; called by muse, mutect2, varscan2
